Somatic mutation profile of tumor specimen CDDP-ABK4-TTP1-A (aliquot CDDP-ABK4-TTP1-A-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABK4, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 51 years.
Specimen CDDP-ABK4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1dd0de34-ab3c-4d80-8d0d-008c1fea1a29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABK4-NB1-A (Blood Derived Normal), aliquot CDDP-ABK4-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50076608-397e-4596-949b-291d5698f840

The open-access MAF lists 263 somatic variants for this specimen: 176 protein-altering or splice-affecting, 53 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 154, Silent 53, Intron 11, RNA 9, Frame Shift Del 8, Nonsense Mutation 7, 5'Flank 5, 3'UTR 4, 5'UTR 3, Splice Site 3, Splice Region 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 1875/2379 reads (79%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.10336G>T p.E3446* | Nonsense Mutation (SNP) | VAF 83/211 reads (39%) | catalogued as COSV71294239; called by muse, mutect2, varscan2
- ADA | c.95G>T p.R32M | Missense Mutation (SNP) | VAF 177/503 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV65740814; called by muse, mutect2, varscan2
- ADAMTS20 | c.4211C>T p.P1404L | Missense Mutation (SNP) | VAF 77/103 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67139254; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 104/146 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1318195753, COSV52825424, COSV52826901; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 175/321 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as COSV54469215, COSV99718784; called by muse, mutect2, varscan2
- ADGRB3 | c.2927C>A p.T976K | Missense Mutation (SNP) | VAF 108/238 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); catalogued as COSV53260113; called by muse, varscan2
- ADGRL3 | c.1961G>T p.G654V (on ENST00000506720 / NM_001322402.2; = p.G586V on NM_015236.6) | Missense Mutation (SNP) | VAF 76/319 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV63368577; called by muse, mutect2, varscan2
- AL136295.1 | c.609A>T p.P203= | Splice Region (SNP) | VAF 107/245 reads (44%) | catalogued as COSV55305103; called by muse, mutect2, varscan2
- AMPD2 | c.1480A>T p.R494W | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as COSV56650631; called by muse, mutect2, varscan2
- ARG2 | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 175/554 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV55777138; called by muse, mutect2, varscan2
- ARHGAP32 | c.5657G>T p.R1886M (on ENST00000310343 / NM_001378025.1; = p.R1537M on NM_014715.4) | Missense Mutation (SNP) | VAF 239/548 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV59855664; called by muse, mutect2, varscan2
- ARHGEF4 | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV58130201; called by muse, mutect2, varscan2
- ARMH4 | c.1963G>C p.G655R | Missense Mutation (SNP) | VAF 427/1113 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50773802; called by muse, mutect2, varscan2
- ATP8A2 | c.3163G>C p.A1055P | Missense Mutation (SNP) | VAF 178/394 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV54970536, COSV54976608; called by muse, mutect2, varscan2
- AURKA | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 241/500 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as COSV57170217; called by muse, mutect2, varscan2
- BCLAF1 | c.848del p.R283Hfs*55 | Frame Shift Del (DEL) | VAF 62/550 reads (11%) | catalogued as COSV62140508; called by mutect2, pindel
- BTD | c.1331G>C p.G444A | Missense Mutation (SNP) | VAF 14/279 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.279); catalogued as COSV100329407; called by muse, mutect2
- C1QTNF8 | c.608A>T p.Q203L | Missense Mutation (SNP) | VAF 74/133 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60519779; called by muse, mutect2, varscan2
- CACNA1G | c.1303G>C p.E435Q | Missense Mutation (SNP) | VAF 282/944 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV61739389; called by muse, mutect2, varscan2
- CACNA1H | c.1660G>T p.G554C | Missense Mutation (SNP) | VAF 60/105 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV62003618; called by muse, mutect2, varscan2
- CAND1 | c.1804G>C p.D602H | Missense Mutation (SNP) | VAF 332/1032 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73389781; called by muse, mutect2, varscan2
- CCNO | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 230/473 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57005166; called by muse, mutect2, varscan2
- CDH20 | c.2250C>G p.F750L | Missense Mutation (SNP) | VAF 165/424 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV53015064, COSV53018004, COSV99405096; called by muse, mutect2, varscan2
- CDH22 | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 15/256 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64837691; called by muse, mutect2
- CDH9 | c.2113C>A p.P705T | Missense Mutation (SNP) | VAF 169/418 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV50449579, COSV99144167; called by muse, mutect2, varscan2
- CELSR3 | c.9332G>A p.R3111Q | Missense Mutation (SNP) | VAF 154/361 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.108); catalogued as rs200542829, COSV51150147; called by muse, mutect2, varscan2
- CEP164 | c.2106G>T p.E702D | Missense Mutation (SNP) | VAF 221/505 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1291164061; called by muse, mutect2, varscan2
- CHAT | c.2141G>T p.S714I | Missense Mutation (SNP) | VAF 311/714 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV60333021; called by muse, mutect2, varscan2
- CMA1 | c.116T>A p.L39Q | Missense Mutation (SNP) | VAF 136/307 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51626380; called by muse, mutect2, varscan2
- CNTN4 | c.2738C>T p.S913L | Missense Mutation (SNP) | VAF 133/667 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as rs1428371855, COSV100639714, COSV61881121; called by muse, mutect2, varscan2
- CNTNAP2 | c.1651A>T p.M551L | Missense Mutation (SNP) | VAF 137/316 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62256425; called by muse, mutect2, varscan2
- COL14A1 | c.1177G>T p.G393* | Nonsense Mutation (SNP) | VAF 71/156 reads (46%) | catalogued as COSV52868297; called by muse, mutect2, varscan2
- CRB2 | c.658T>C p.C220R | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1024210800, COSV63505566; called by muse, mutect2, varscan2
- CTNND2 | c.2362G>A p.D788N | Missense Mutation (SNP) | VAF 150/359 reads (42%) | SIFT tolerated (0.92); PolyPhen benign (0.272); catalogued as COSV58927278; called by muse, mutect2, varscan2
- CXCR3 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 35/37 reads (95%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as rs1438602944, COSV65461977; called by muse, mutect2, varscan2
- DLX4 | c.18C>A p.C6* | Nonsense Mutation (SNP) | VAF 44/92 reads (48%) | catalogued as rs754849816, COSV53592981; called by muse, mutect2
- ELP1 | c.489G>T p.W163C | Missense Mutation (SNP) | VAF 326/909 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65899934; called by muse, mutect2, varscan2
- ESRRB | c.122C>G p.A41G | Missense Mutation (SNP) | VAF 243/420 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.387); catalogued as COSV55067210; called by muse, mutect2, varscan2
- FAM174A | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs769645263, COSV57063535, COSV57065743; called by muse, mutect2, varscan2
- FBXO40 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 267/413 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57527521; called by muse, mutect2, varscan2
- FER | c.2194C>G p.L732V | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55305627; called by muse, mutect2, varscan2
- FLG | c.2818A>T p.R940W | Missense Mutation (SNP) | VAF 2186/2593 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV64249146; called by muse, mutect2, varscan2
- FLNC | c.3762G>T p.K1254N | Missense Mutation (SNP) | VAF 222/531 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV57964918; called by muse, mutect2, varscan2
- FLT1 | c.1402T>G p.W468G | Missense Mutation (SNP) | VAF 318/742 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56742786; called by muse, mutect2, varscan2
- FOXN4 | c.1293G>T p.Q431H | Missense Mutation (SNP) | VAF 133/155 reads (86%) | SIFT tolerated (0.08); PolyPhen benign (0.267); catalogued as COSV54497842; called by muse, mutect2, varscan2
- GAL3ST2 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (0.89); PolyPhen benign (0.012); catalogued as rs1279618052, COSV51951677; called by muse, mutect2, varscan2
- GATA5 | c.437T>A p.V146E | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV53347455; called by muse, mutect2, varscan2
- GJA8 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 55/419 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.713); catalogued as COSV53790632; called by muse, mutect2, varscan2
- GLIS2 | c.649A>G p.N217D | Missense Mutation (SNP) | VAF 113/400 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV52111930; called by muse, mutect2, varscan2
- GLRA3 | c.434C>A p.T145N | Missense Mutation (SNP) | VAF 111/330 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56870148, COSV99927070; called by muse, mutect2, varscan2
- GLYATL2 | c.799A>C p.S267R | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.034); catalogued as COSV54851536; called by muse, mutect2, varscan2
- GPNMB | c.297C>A p.N99K | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.122); catalogued as COSV51701039; called by muse, mutect2, varscan2
- GRIP2 | c.1544C>T p.P515L (on ENST00000619221; = p.P418L on NM_001080423.4) | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs764423291; called by muse, mutect2, varscan2
- HEATR5B | c.564T>A p.D188E | Missense Mutation (SNP) | VAF 98/239 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51859055; called by muse, mutect2, varscan2
- HIPK1 | c.3320G>T p.S1107I (on ENST00000369558 / NM_001369806.1; = p.S713I on NM_181358.2) | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV61250655; called by muse, mutect2, varscan2
- IGKV1D-42 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 144/265 reads (54%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.632); catalogued as rs1216180803; called by muse, mutect2, varscan2
- INCENP | c.1097A>T p.E366V | Missense Mutation (SNP) | VAF 100/255 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV53920971; called by muse, mutect2, varscan2
- ISM2 | c.563T>A p.L188Q | Missense Mutation (SNP) | VAF 101/228 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53636984; called by muse, mutect2, varscan2
- KHDC3L | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 301/714 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.183); catalogued as rs755627817, COSV64864083; called by muse, mutect2, varscan2
- KIF2B | c.1437A>T p.K479N | Missense Mutation (SNP) | VAF 153/291 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52135284; called by muse, mutect2, varscan2
- LCE3D | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 108/1210 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.419); catalogued as COSV64231211, COSV64231324; called by muse, mutect2
- LMF1 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV51902501; called by muse, mutect2, varscan2
- LRP1 | c.4936G>T p.G1646C | Missense Mutation (SNP) | VAF 828/1123 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54525708; called by muse, mutect2, varscan2
- LRRN2 | c.35G>C p.W12S | Missense Mutation (SNP) | VAF 308/422 reads (73%) | SIFT tolerated (0.49); PolyPhen benign (0.026); catalogued as COSV65784689; called by muse, mutect2, varscan2
- LYNX1 | c.210G>C p.E70D | Missense Mutation (SNP) | VAF 115/242 reads (48%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.848); catalogued as COSV59988512, COSV59990068; called by muse, mutect2, varscan2
- MDH1 | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 80/413 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51865080; called by muse, mutect2, varscan2
- MDM2 | c.253A>G p.N85D | Missense Mutation (SNP) | VAF 137/954 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV50703927; called by muse, mutect2, varscan2
- MEGF10 | c.3160C>A p.P1054T | Missense Mutation (SNP) | VAF 138/397 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57256289; called by muse, mutect2, varscan2
- MLXIPL | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 165/738 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.23); catalogued as COSV57670389; called by muse, mutect2, varscan2
- MRGPRX3 | c.271C>A p.R91S | Missense Mutation (SNP) | VAF 192/471 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs753026066, COSV66934821; called by muse, mutect2, varscan2
- MROH2B | c.12T>G p.S4R | Missense Mutation (SNP) | VAF 115/307 reads (37%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV68189472; called by muse, mutect2, varscan2
- MTA3 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as COSV68136690; called by muse, mutect2, varscan2
- MUC12 | c.13124C>A p.P4375H (on ENST00000379442; = p.P4232H on NM_001164462.1) | Missense Mutation (SNP) | VAF 103/637 reads (16%) | SIFT deleterious (0); catalogued as COSV65189509; called by muse, mutect2, varscan2
- MYOZ1 | c.431C>A p.T144K | Missense Mutation (SNP) | VAF 216/461 reads (47%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV63772626; called by muse, mutect2, varscan2
- MYPN | c.3887C>A p.S1296Y | Missense Mutation (SNP) | VAF 310/744 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62739354; called by mutect2, varscan2
- NAP1L3 | c.621G>T p.K207N | Missense Mutation (SNP) | VAF 313/357 reads (88%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV59077644; called by muse, mutect2, varscan2
- NHSL1 | c.2794C>G p.P932A | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.023); catalogued as COSV58683245; called by muse, mutect2, varscan2
- NID2 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 116/232 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV53502797; called by muse, mutect2, varscan2
- NLGN3 | c.2141T>C p.V714A (on ENST00000358741 / NM_181303.2; = p.V694A on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 237/264 reads (90%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV62445260; called by muse, mutect2, varscan2
- NLRC3 | c.1553C>A p.S518Y | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV57092839, COSV57095920; called by muse, mutect2, varscan2
- NRXN1 | c.1604T>G p.M535R | Missense Mutation (SNP) | VAF 452/1017 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV58492844; called by muse, mutect2, varscan2
- OBSCN | c.10579A>G p.T3527A | Missense Mutation (SNP) | VAF 221/1221 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52828656; called by muse, mutect2, varscan2
- OLFM2 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 155/666 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs201189277, COSV99321874; called by muse, mutect2, varscan2
- OR2M7 | c.532T>G p.C178G | Missense Mutation (SNP) | VAF 340/1038 reads (33%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1190871802; called by muse, mutect2, varscan2
- OR2V2 | c.184T>A p.F62I | Missense Mutation (SNP) | VAF 161/417 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.237); catalogued as rs868508856, COSV60316487; called by muse, mutect2, varscan2
- OR4D10 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 143/315 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73260206; called by muse, mutect2, varscan2
- OR5L1 | c.853C>A p.L285M | Missense Mutation (SNP) | VAF 154/354 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV61735408; called by muse, mutect2, varscan2
- PABPC4L | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 123/570 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as rs1466240221, COSV69930213; called by mutect2, varscan2
- PAX1 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 292/674 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68273399; called by muse, mutect2, varscan2
- PCARE | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs374283240; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH15 | c.3350C>G p.A1117G | Missense Mutation (SNP) | VAF 139/389 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.101); catalogued as COSV57392905; called by muse, mutect2, varscan2
- PHF21B | c.713T>C p.V238A | Missense Mutation (SNP) | VAF 99/130 reads (76%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.751); catalogued as COSV57562367; called by muse, mutect2, varscan2
- PIK3C3 | c.502T>C p.S168P | Missense Mutation (SNP) | VAF 330/754 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV56284564; called by muse, mutect2, varscan2
- PJA2 | c.1526A>G p.N509S | Missense Mutation (SNP) | VAF 85/231 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.325); catalogued as rs748128479, COSV63274590; called by muse, mutect2, varscan2
- PKHD1L1 | c.2276G>T p.G759V | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV65752907; called by muse, mutect2, varscan2
- PLA2G4C | c.1385C>A p.P462Q | Missense Mutation (SNP) | VAF 290/351 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62787910; called by muse, mutect2, varscan2
- PLCH2 | c.4198G>A p.A1400T | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as COSV53949602; called by muse, mutect2, varscan2
- POU3F3 | c.1291C>A p.P431T | Missense Mutation (SNP) | VAF 137/486 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63722453; called by muse, mutect2, varscan2
- PRDM1 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 158/379 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV64850184, COSV64850618; called by muse, mutect2, varscan2
- PRR23A | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV67214243, COSV67215266; called by muse, mutect2, varscan2
- PSEN1 | c.1369A>G p.M457V | Missense Mutation (SNP) | VAF 269/755 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.99); catalogued as rs1430581353, COSV56196952; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRZ1 | c.2015G>A p.S672N | Missense Mutation (SNP) | VAF 128/282 reads (45%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.023); catalogued as COSV66445430; called by muse, mutect2, varscan2
- PXDNL | c.1335C>A p.N445K | Missense Mutation (SNP) | VAF 202/493 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as COSV62498314; called by muse, mutect2, varscan2
- RASGRP2 | c.746G>C p.G249A | Missense Mutation (SNP) | VAF 271/609 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV62450866; called by muse, mutect2, varscan2
- REEP3 | c.92A>G p.N31S | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV53427312; called by muse, varscan2
- RNFT1 | c.988C>G p.L330V | Missense Mutation (SNP) | VAF 187/366 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.283); catalogued as COSV59870501; called by muse, mutect2, varscan2
- RSL1D1 | c.710T>G p.L237R | Missense Mutation (SNP) | VAF 150/274 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63078516; called by muse, mutect2, varscan2
- RTTN | c.3323G>A p.G1108D | Missense Mutation (SNP) | VAF 202/272 reads (74%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV55352058; called by muse, mutect2, varscan2
- SAP30BP | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 261/488 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53130320; called by muse, mutect2, varscan2
- SELENON | c.1600G>C p.V534L | Missense Mutation (SNP) | VAF 135/502 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.424); catalogued as COSV62524475; called by muse, mutect2, varscan2
- SLC34A2 | c.1273G>T p.G425C | Missense Mutation (SNP) | VAF 449/1019 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65943157; called by muse, mutect2, varscan2
- SLIT3 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 144/423 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60620446, COSV60633112; called by muse, mutect2, varscan2
- SPATA31A3 | c.2242G>A p.V748M | Missense Mutation (SNP) | VAF 146/346 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1468994246; called by mutect2, varscan2
- SPTA1 | c.3763G>T p.D1255Y | Missense Mutation (SNP) | VAF 113/670 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV63759296; called by muse, mutect2, varscan2
- STK11 | c.286A>T p.K96* | Nonsense Mutation (SNP) | VAF 158/174 reads (91%) | catalogued as COSV58821977; called by muse, mutect2, varscan2
- SUPT4H1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 109/200 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.097); catalogued as COSV56643490, COSV99842778; called by muse, mutect2, varscan2
- SURF6 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 182/470 reads (39%) | catalogued as COSV64395847; called by muse, mutect2
- TAF2 | c.2895G>T p.W965C | Missense Mutation (SNP) | VAF 221/614 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV65421085; called by muse, mutect2, varscan2
- TANK | c.917C>G p.T306S | Missense Mutation (SNP) | VAF 591/1401 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.048); catalogued as COSV52047580, COSV52047833; called by muse, mutect2, varscan2
- TBX15 | c.1153G>T p.G385C (on ENST00000369429 / NM_001330677.2; = p.G279C on NM_152380.3) | Missense Mutation (SNP) | VAF 215/778 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.817); catalogued as COSV52876419; called by muse, mutect2, varscan2
- TDRD9 | c.2071C>G p.R691G | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV59156031; called by muse, mutect2, varscan2
- TG | c.5284G>T p.V1762F | Missense Mutation (SNP) | VAF 304/738 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.215); catalogued as COSV55077567; called by muse, mutect2, varscan2
- TGFBI | c.1339A>T p.K447* | Nonsense Mutation (SNP) | VAF 230/518 reads (44%) | catalogued as rs1453112062, COSV59354409; called by muse, varscan2
- TIGD3 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.193); catalogued as COSV52891356; called by muse, mutect2, varscan2
- TMEM145 | c.76dup p.R26Pfs*40 | Frame Shift Ins (INS) | VAF 10/12 reads (83%) | catalogued as rs1245316407; called by mutect2, varscan2
- TNN | c.2596T>G p.W866G | Missense Mutation (SNP) | VAF 317/674 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53435421; called by muse, mutect2, varscan2
- TPI1 | c.508G>A p.D170N (on ENST00000229270; = p.D133N on NM_000365.6) | Missense Mutation (SNP) | VAF 326/1037 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV51289974; called by muse, mutect2, varscan2
- TRPC7 | c.1619C>T p.S540L | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1397780134, COSV100726040, COSV61460424; called by muse, mutect2
- TTN | c.42489G>T p.R14163S (on ENST00000591111; = p.R6739S on NM_003319.4) | Missense Mutation (SNP) | VAF 287/684 reads (42%) | PolyPhen benign (0.083); catalogued as rs759143403, COSV60344861; ClinVar: not provided; called by muse, varscan2
- TXNDC16 | c.614A>T p.D205V | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV55987523; called by muse, varscan2
- UNC79 | c.5560G>T p.D1854Y (on ENST00000393151 / NM_001346218.2; = p.D1677Y on NM_020818.5) | Missense Mutation (SNP) | VAF 184/331 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56410541, COSV56413995; called by muse, mutect2, varscan2
- UPF3B | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 166/185 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV52229760; called by muse, mutect2, varscan2
- VSTM2A | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 133/324 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV56496612; called by muse, mutect2, varscan2
- VWA1 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs373787092, COSV58600696; called by muse, mutect2, varscan2
- WDR90 | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 102/178 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV53475214; called by muse, mutect2, varscan2
- XIRP1 | c.2321C>T p.T774I | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV61141096; called by muse, mutect2, varscan2
- XYLT1 | c.1698G>T p.K566N | Missense Mutation (SNP) | VAF 173/330 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV54496601; called by muse, mutect2, varscan2
- ZAN | c.3704G>T p.G1235V | Missense Mutation (SNP) | VAF 121/264 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1426145741; called by muse, mutect2, varscan2
- ZER1 | c.1118G>C p.R373P | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52565998, COSV52568611; called by muse, mutect2, varscan2
- ZIC3 | c.1388A>C p.N463T | Missense Mutation (SNP) | VAF 305/343 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54977187; called by muse, mutect2, varscan2
- ZNF217 | c.2770G>T p.V924L | Missense Mutation (SNP) | VAF 223/457 reads (49%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as COSV56602427; called by muse, mutect2, varscan2
- ZNF398 | c.1554G>T p.K518N (on ENST00000475153 / NM_170686.3; = p.K347N on NM_020781.4) | Missense Mutation (SNP) | VAF 224/590 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60066790; called by muse, mutect2, varscan2
- ZNF423 | c.2698G>A p.G900R (on ENST00000563137 / NM_001379286.1; = p.G892R on NM_015069.4) | Missense Mutation (SNP) | VAF 152/412 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV52204459, COSV99281016; called by muse, mutect2, varscan2
- ZNF585B | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 117/436 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57217000; called by muse, mutect2, varscan2
- ZNF853 | c.1509C>G p.H503Q | Missense Mutation (SNP) | VAF 75/206 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV71923108; called by muse, mutect2, varscan2
- ZP4 | c.1606G>T p.D536Y | Missense Mutation (SNP) | VAF 197/278 reads (71%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.133); catalogued as COSV63913428; called by muse, mutect2, varscan2
- ZP4 | c.1247G>T p.R416L | Missense Mutation (SNP) | VAF 68/503 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753993472, COSV63913430; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 105/232 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- BIN2 | c.1696del p.*566Efs*23 | Frame Shift Del (DEL) | VAF 178/293 reads (61%) | called by mutect2, pindel, varscan2
- C17orf50 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 164/204 reads (80%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.2869-2A>T p.X957_splice | Splice Site (SNP) | VAF 121/327 reads (37%) | called by muse, mutect2, varscan2
- CAPN12 | c.394del p.Q132Sfs*34 | Frame Shift Del (DEL) | VAF 280/438 reads (64%) | called by mutect2, pindel, varscan2
- CNTNAP4 | c.928-1G>T p.X310_splice | Splice Site (SNP) | VAF 70/178 reads (39%) | called by muse, varscan2
- EIF2B5 | c.2130+6T>A | Splice Region (SNP) | VAF 146/889 reads (16%) | called by muse, mutect2, varscan2
- FOLH1 | c.783del p.N262Mfs*45 | Frame Shift Del (DEL) | VAF 148/536 reads (28%) | called by mutect2, pindel, varscan2
- GRIP2 | c.1543C>T p.P515S (on ENST00000619221; = p.P418S on NM_001080423.4) | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMCN1 | c.12626T>C p.L4209S | Missense Mutation (SNP) | VAF 16/462 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2
- HSPA9 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 273/680 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- KEAP1 | c.1344_1361del p.E449_A454del | In Frame Del (DEL) | VAF 310/404 reads (77%) | called by mutect2, pindel, varscan2
- MUC5AC | c.16340G>C p.C5447S | Missense Mutation (SNP) | VAF 73/262 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NMNAT2 | c.257A>T p.E86V | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPTX2 | c.23G>A p.S8N | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- PEAR1 | c.2667C>A p.S889R | Missense Mutation (SNP) | VAF 66/457 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PPP6R2 | c.618+1G>A p.X206_splice | Splice Site (SNP) | VAF 88/117 reads (75%) | called by muse, mutect2, varscan2
- RBM10 | c.2387del p.L796Cfs*6 | Frame Shift Del (DEL) | VAF 396/594 reads (67%) | called by mutect2, pindel, varscan2
- SORL1 | c.6550G>T p.A2184S | Missense Mutation (SNP) | VAF 140/354 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- STMND1 | c.550del p.E184Kfs*4 | Frame Shift Del (DEL) | VAF 24/97 reads (25%) | called by mutect2, pindel
- TNP1 | c.63C>A p.H21Q | Missense Mutation (SNP) | VAF 24/821 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); called by muse, mutect2
- TTC28 | c.5620C>A p.Q1874K | Missense Mutation (SNP) | VAF 130/156 reads (83%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TTC37 | c.4065T>G p.S1355R | Missense Mutation (SNP) | VAF 13/416 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.144); called by muse, mutect2
- VNN3 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 87/208 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VPS35L | c.672del p.Q225Sfs*54 | Frame Shift Del (DEL) | VAF 92/218 reads (42%) | called by mutect2, pindel, varscan2
- VWDE | c.2836A>G p.R946G | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- ZBBX | c.1230T>G p.I410M | Missense Mutation (SNP) | VAF 144/220 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ZNF717 | c.2722del p.Q908Kfs*34 | Frame Shift Del (DEL) | VAF 18/214 reads (8%) | called by mutect2, pindel
- ABCA13 | c.10335G>T p.L3445= | Silent (SNP) | VAF 86/215 reads (40%) | catalogued as COSV71294237; called by muse, mutect2, varscan2
- ADAMTS17 | c.720C>T p.A240= | Silent (SNP) | VAF 86/258 reads (33%) | catalogued as rs1365475548, COSV51493563; called by muse, mutect2, varscan2
- AGBL4 | c.423C>T p.D141= | Silent (SNP) | VAF 156/305 reads (51%) | catalogued as rs1313513592, COSV65760833; called by muse, mutect2, varscan2
- ANKFN1 | c.2814A>T p.A938= (on ENST00000653862; = p.A791= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 215/676 reads (32%) | called by muse, mutect2, varscan2
- BBS4 | c.1356C>A p.T452= | Silent (SNP) | VAF 197/850 reads (23%) | catalogued as COSV51440401; called by muse, mutect2, varscan2
- C7 | c.909T>C p.Y303= | Silent (SNP) | VAF 102/306 reads (33%) | catalogued as COSV57480928; called by muse, mutect2, varscan2
- CD1B | c.75G>A p.P25= | Silent (SNP) | VAF 172/240 reads (72%) | catalogued as rs779464101, COSV63805196; called by muse, mutect2, varscan2
- CD22 | c.1227G>C p.P409= | Silent (SNP) | VAF 130/159 reads (82%) | catalogued as rs376828655, COSV50068113, COSV99323741; called by muse, mutect2, varscan2
- CFAP46 | c.5728C>T p.L1910= | Silent (SNP) | VAF 195/433 reads (45%) | catalogued as COSV54159466; called by muse, mutect2, varscan2
- CGREF1 | c.903C>A p.I301= (on ENST00000260595; = p.I318= on NM_006569.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs541426747, COSV53151971; called by muse, varscan2
- CLDN25 | c.600T>G p.A200= | Silent (SNP) | VAF 179/472 reads (38%) | called by muse, mutect2, varscan2
- CMA1 | c.115C>T p.L39= | Silent (SNP) | VAF 134/305 reads (44%) | catalogued as COSV51626393; called by muse, mutect2, varscan2
- COL13A1 | c.1242A>G p.P414= (on ENST00000398978 / NM_001130103.2; = p.P357= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/313 reads (16%) | catalogued as COSV62575129; called by muse, mutect2, varscan2
- CSMD3 | c.2379G>C p.G793= (on ENST00000297405 / NM_001363185.1; = p.G689= on NM_052900.3) | Silent (SNP) | VAF 174/393 reads (44%) | catalogued as COSV52170385, COSV52317130; called by muse, mutect2, varscan2
- DCC | c.1920A>G p.K640= | Silent (SNP) | VAF 229/591 reads (39%) | catalogued as COSV59108165, COSV59135006; called by muse, mutect2
- DMRT3 | c.691C>T p.L231= | Silent (SNP) | VAF 186/232 reads (80%) | catalogued as COSV51908703; called by muse, mutect2, varscan2
- DNAH11 | c.1635G>A p.L545= | Silent (SNP) | VAF 61/136 reads (45%) | catalogued as COSV60980976; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2553C>T p.R851= | Silent (SNP) | VAF 181/278 reads (65%) | catalogued as rs745688760, COSV62566583; called by muse, mutect2, varscan2
- ENPP2 | c.150C>T p.S50= | Silent (SNP) | VAF 103/236 reads (44%) | called by muse, mutect2, varscan2
- EVC | c.333A>G p.T111= | Silent (SNP) | VAF 413/954 reads (43%) | catalogued as COSV53838013; called by muse, mutect2, varscan2
- FANCM | c.4302T>G p.V1434= | Silent (SNP) | VAF 77/306 reads (25%) | catalogued as COSV57506561; called by muse, mutect2, varscan2
- FHOD3 | c.2545T>C p.L849= (on ENST00000359247 / NM_001281739.3; = p.L866= on NM_025135.5) | Silent (SNP) | VAF 110/292 reads (38%) | catalogued as rs1186968717, COSV57188481; called by muse, varscan2
- FIBIN | c.457C>A p.R153= | Silent (SNP) | VAF 82/176 reads (47%) | catalogued as COSV59412499, COSV59413519; called by muse, mutect2, varscan2
- FOXD4L6 | c.876C>A p.T292= | Silent (SNP) | VAF 86/194 reads (44%) | called by mutect2, varscan2
- GABRA1 | c.1104C>T p.Y368= | Silent (SNP) | VAF 161/327 reads (49%) | catalogued as rs771832995, COSV50099123, COSV99196334; ClinVar: likely benign; called by muse, mutect2, varscan2
- GABRQ | c.474G>A p.V158= | Silent (SNP) | VAF 207/239 reads (87%) | catalogued as COSV64783882; called by muse, varscan2
- GRHL1 | c.1305G>A p.K435= | Silent (SNP) | VAF 94/257 reads (37%) | called by muse, mutect2, varscan2
- HHIPL1 | c.1623C>A p.I541= | Silent (SNP) | VAF 96/192 reads (50%) | catalogued as COSV58093508; called by muse, mutect2, varscan2
- HNRNPH1 | c.639T>A p.P213= | Silent (SNP) | VAF 147/299 reads (49%) | catalogued as COSV61488326; called by muse, mutect2, varscan2
- IRF2BP1 | c.990G>T p.L330= | Silent (SNP) | VAF 279/317 reads (88%) | catalogued as COSV56195137; called by muse, mutect2, varscan2
- LRRTM4 | c.795C>A p.I265= | Silent (SNP) | VAF 155/356 reads (44%) | catalogued as COSV69142202; called by muse, mutect2, varscan2
- MYOM3 | c.2349C>A p.G783= | Silent (SNP) | VAF 87/172 reads (51%) | catalogued as rs573631755, COSV58400983; called by muse, mutect2, varscan2
- MYT1L | c.1695C>A p.S565= | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as COSV67727150, COSV67732427; called by muse, mutect2, varscan2
- NGFR | c.735A>C p.R245= | Silent (SNP) | VAF 401/701 reads (57%) | catalogued as COSV50804418; called by muse, mutect2, varscan2
- ODF3 | c.72C>T p.S24= | Silent (SNP) | VAF 23/134 reads (17%) | catalogued as COSV57295145; called by muse, mutect2, varscan2
- OTOGL | c.5922A>G p.P1974= (on ENST00000547103; = p.P1965= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 82/100 reads (82%) | catalogued as COSV54023624; called by muse, mutect2, varscan2
- PCDHA6 | c.1758T>G p.G586= | Silent (SNP) | VAF 257/739 reads (35%) | catalogued as COSV65345175, COSV65347543; called by muse, mutect2, varscan2
- PCLO | c.1815C>A p.A605= | Silent (SNP) | VAF 112/470 reads (24%) | catalogued as COSV61665756; called by mutect2, varscan2
- PDE6C | c.1818C>T p.H606= | Silent (SNP) | VAF 160/379 reads (42%) | catalogued as COSV65117704; called by muse, mutect2, varscan2
- PGBD2 | c.291A>T p.P97= | Silent (SNP) | VAF 708/874 reads (81%) | catalogued as rs1330007999, COSV61401130; called by muse, mutect2, varscan2
- PHLDB2 | c.2925T>C p.Y975= (on ENST00000393925 / NM_001134439.2; = p.Y932= on NM_145753.2) | Silent (SNP) | VAF 32/133 reads (24%) | catalogued as COSV67316091; called by muse, mutect2, varscan2
- PKM | c.273G>C p.V91= | Silent (SNP) | VAF 83/529 reads (16%) | called by muse, mutect2, varscan2
- PLEC | c.11613G>T p.L3871= (on ENST00000322810 / NM_201380.4; = p.L3761= on NM_000445.5) | Silent (SNP) | VAF 137/286 reads (48%) | catalogued as COSV59694768; called by muse, mutect2, varscan2
- PLIN3 | c.393G>T p.G131= | Silent (SNP) | VAF 178/210 reads (85%) | catalogued as COSV55737152; called by muse, mutect2, varscan2
- PPP2CA | c.303A>C p.V101= | Silent (SNP) | VAF 176/348 reads (51%) | catalogued as COSV51539139; called by muse, mutect2, varscan2
- RTL4 | c.678A>G p.L226= | Silent (SNP) | VAF 107/119 reads (90%) | catalogued as COSV61207348; called by muse, mutect2, varscan2
- RYR2 | c.11406C>T p.V3802= | Silent (SNP) | VAF 42/376 reads (11%) | called by muse, varscan2
- RYR3 | c.5211G>T p.V1737= | Silent (SNP) | VAF 100/428 reads (23%) | catalogued as COSV66808204; called by mutect2, varscan2
- SALL1 | c.2176A>C p.R726= | Silent (SNP) | VAF 180/433 reads (42%) | catalogued as COSV51764570; called by muse, mutect2, varscan2
- SARM1 | c.2004G>C p.L668= | Silent (SNP) | VAF 452/692 reads (65%) | catalogued as COSV50229806; called by muse, mutect2, varscan2
- ST8SIA3 | c.519G>A p.G173= | Silent (SNP) | VAF 153/382 reads (40%) | catalogued as rs1002865494, COSV60655348; called by muse, mutect2, varscan2
- STK17B | c.105A>G p.T35= | Silent (SNP) | VAF 113/276 reads (41%) | catalogued as rs771300169; called by muse, mutect2, varscan2
- UBE2O | c.3828C>T p.F1276= | Silent (SNP) | VAF 41/130 reads (32%) | catalogued as COSV60067700; called by muse, mutect2, varscan2
- ACADM | chr1:75724695 C>T | 5'Flank (SNP) | VAF 14/49 reads (29%) | catalogued as rs1209338599; called by muse, varscan2
- AL353804.4 | chrX:73823464 G>A | 5'Flank (SNP) | VAF 170/194 reads (88%) | called by muse, mutect2, varscan2
- AL355390.1 | n.281T>C | RNA (SNP) | VAF 108/230 reads (47%) | called by muse, mutect2
- AL355390.1 | n.279C>A | RNA (SNP) | VAF 106/226 reads (47%) | called by muse, mutect2
- AL590867.2 | n.403G>T | RNA (SNP) | VAF 228/564 reads (40%) | called by muse, mutect2, varscan2
- ANKK1 | c.481-199G>A | Intron (SNP) | VAF 100/260 reads (38%) | called by muse, mutect2, varscan2
- AP002495.1 | c.436+28G>T | Intron (SNP) | VAF 240/475 reads (51%) | called by muse, mutect2, varscan2
- AP002495.1 | c.436+27G>T | Intron (SNP) | VAF 241/479 reads (50%) | called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+38778G>T | Intron (SNP) | VAF 154/649 reads (24%) | called by muse, mutect2, varscan2
- FEZ1 | c.-46+708G>C | Intron (SNP) | VAF 8/191 reads (4%) | called by muse, mutect2
- GDAP1L1 | c.*469C>A | 3'UTR (SNP) | VAF 130/319 reads (41%) | called by muse, mutect2, varscan2
- GOLGA8IP | n.224T>A | RNA (SNP) | VAF 43/152 reads (28%) | called by mutect2, varscan2
- IGFBP5 | c.338-45C>A | Intron (SNP) | VAF 157/407 reads (39%) | called by muse, mutect2, varscan2
- ISLR2 | chr15:74128523 C>A | 5'Flank (SNP) | VAF 78/293 reads (27%) | called by muse, mutect2, varscan2
- LINC01956 | n.443G>T | RNA (SNP) | VAF 77/149 reads (52%) | called by muse, mutect2, varscan2
- LMO2 | c.42-33G>A | Intron (SNP) | VAF 183/429 reads (43%) | called by muse, mutect2, varscan2
- LTN1 | chr21:28992919 C>A | 5'Flank (SNP) | VAF 94/236 reads (40%) | catalogued as COSV57478314; called by muse, mutect2, varscan2
- MSX1 | c.-4C>A | 5'UTR (SNP) | VAF 63/108 reads (58%) | called by muse, mutect2, varscan2
- MTO1 | c.1130-59C>G | Intron (SNP) | VAF 119/269 reads (44%) | called by muse, mutect2, varscan2
- NAXD | chr13:110615631 C>T | 5'Flank (SNP) | VAF 41/94 reads (44%) | catalogued as COSV59396143; called by muse, mutect2, varscan2
- OR2W5 | n.969T>C | RNA (SNP) | VAF 315/767 reads (41%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.4153C>G | RNA (SNP) | VAF 60/126 reads (48%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.932C>T | RNA (SNP) | VAF 25/155 reads (16%) | catalogued as rs138521906; called by muse, mutect2, varscan2
- SLC1A3 | c.181+4214G>A | Intron (SNP) | VAF 56/202 reads (28%) | catalogued as rs568528047; called by muse, mutect2, varscan2
- SPDYE1 | chr7:44013575 G>C | 3'Flank (SNP) | VAF 90/216 reads (42%) | called by muse, mutect2, varscan2
- SPSB2 | c.*4C>T | 3'UTR (SNP) | VAF 168/484 reads (35%) | catalogued as rs368797936; called by muse, varscan2
- SYNDIG1 | c.*23G>C | 3'UTR (SNP) | VAF 98/247 reads (40%) | called by muse, mutect2, varscan2
- THRA | c.1110+34_1110+36del | Intron (DEL) | VAF 164/225 reads (73%) | called by mutect2, pindel, varscan2
- TMEM179 | c.*2066G>T | 3'UTR (SNP) | VAF 180/365 reads (49%) | called by muse, mutect2, varscan2
- TUBB7P | n.193C>A | RNA (SNP) | VAF 155/471 reads (33%) | called by muse, mutect2, varscan2
- UVSSA | c.1753-186C>A | Intron (SNP) | VAF 55/185 reads (30%) | called by muse, mutect2, varscan2
- Unknown | chr8:74752528 ins T | IGR (INS) | VAF 73/209 reads (35%) | called by mutect2, pindel, varscan2
- ZNF559-ZNF177 | c.-28G>A | 5'UTR (SNP) | VAF 75/174 reads (43%) | called by muse, mutect2, varscan2
- ZNF738 | c.-25G>T | 5'UTR (SNP) | VAF 457/520 reads (88%) | catalogued as rs777351263; called by muse, mutect2, varscan2
